TCGA case TCGA-ZN-A9VU — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Brigham and Women's Hospital Division of Thoracic Surgery. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f15667dc-8376-40b6-84b2-8f5370c3d66a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Alive.

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 70.4 years (25,714 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 977 days (2.7 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 679 days (1.9 years); Days to treatment end: 707 days (1.9 years); Treatment dose: 5,000 cGy; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 72.0 years (26,299 days); Days to diagnosis: 585 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 588 days (1.6 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 585 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 585 days (1.6 years).
- Days to follow up: 739 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 977 days (2.7 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; Timepoint: Preoperative.
- Imaging anatomic site: Pleura; Imaging suv max: 6; Timepoint: Prior to Treatment.

Molecular and laboratory tests
- Serum Mesothelin 2.3 nmol/L [Blood test normal range lower: 0; Blood test normal range upper: 1.5].
- Creatinine 0.82 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.2].

Exposures
- Occupation type: Building Finishers and Related Trades Workers.
- Exposure type: Asbestos; Exposure source: Occupational.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZN-A9VU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-ZN-A9VU-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-ZN-A9VU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZN-A9VU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: plumber.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Serum mesothelin prior treatment: 2.3; Suv of pleura max: 6.0.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 977 days; disease-specific survival: no event (censored), 977 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 585 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZN-A9VU-01A-11D-A39Q-01): tumor purity 0.61, ploidy 1.97, whole-genome doublings 0.
